Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A3J5, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A3J5-06A (Metastatic).

[page 1 of 3]
REPORT COPY
from

DEPARTMENT OF ANATOMICAL PATHOLOGY

Enquiries :

REQUESTING DR :
VERIFIED BY :

SPECIMEN DATE :
ACCESSION :

REPORTED BY

Please note: SEE ALSO ADDENDUM REPORT ON THIS CASE

Reported by:

Previous Lab. Ref:

CLINICAL INFORMATION

Metastatic melanoma (R) groin + (R) calf
TCGA sample.

OPERATION/NATURE OF SPEC

1. Tumour (R) groin. 2. Tumour (R) calf. 3. Bx (R) calf -> ?melanoma.

MACROSCOPIC DESCRIPTION

Three specimens were received.

I. "(1) tumour right groin". A piece of fatty tissue, 40 x 35 x 20mm with an overlying ellipse of skin, 38 x 9mm. No abnormalities on the skin surface. The surgical margins were inked. Sectioning reveals a well-circumscribed pale tan and dark brown nodule 14 x 10mm in the subcutaneous fat, which extends to above the deep surgical margin. One representative section embedded in one block.

II. "(2) lesion right upper calf". An ellipse of skin, 20 x 6 x 8mm, bearing a ? transverse scar extending from both lateral margins. A nodule can be palpate in the subcutaneous fat 10 x 5 x 4mm. The surgical margins were inked. On sectioning, the nodule has a firm, pale tan cut surface. Two representative sections embedded in one block.

III. "Biopsy adjacent to nodule right calf". A pale tan biopsy, up to 5mm across. Embedded whole in one block.

MICROSCOPIC DESCRIPTION

I. "(1) tumour right groin": Sections show a piece of fibroadipose tissue that includes a circumscribed tumour nodule composed of pleomorphic spindle and epithelioid cells consistent with metastatic malignant melanoma. While there are a few lymphocytes around the periphery of the tumour in some areas,

1CD-0-3
Melanoma, NOS 8720/3
Site: skin, groin C44.5
pw 9/26/12

[page 2 of 3]
REPORT COPY
from

DEPARTMENT OF ANATOMICAL PATHOLOGY

Professor

Enquiries

REQUESTING DR :
Verified by :

SPECIMEN DATE :
ACCESSION

MICROSCOPIC DESCRIPTION ...Cont'd

no convincing evidence of a pre-existing lymph node is seen . The
margins appear just clear (<0.1mm).

II. "(2) lesion right upper calf": Sections show skin with a deep dermal
deposit of pleomorphic epithelioid and spindle cells consistent with malignant
melanoma. Tumour cells are present at the inked margin.

III. "Biopsy adjacent to nodule right calf": Sections show fibrous tissue
that includes pleomorphic plump and spindle shaped cells consistent with
malignant melanoma.

SEE ADDENDUM REPORT:

DIAGNOSIS

I-III. (R) groin & leg biopsies : consistent with MALIGNANT MELANOMA

SNOMED CODES

Soft tissue - malignant melanoma, metastatic
Skin of leg - malignant melanoma, metastatic
Skin biopsy/resection

***** END OF ACCESSION *****

[page 3 of 3]
REPORT COPY
from

DEPARTMENT OF ANATOMICAL PATHOLOGY

Professor

Inquiries :

REQUESTING DR :
VERIFIED BY :

SPECIMEN DATE :
ACCESSION :

ADDENDUM REPT BY
Reported by :

ADDENDUM MICROSCOPIC REPT

Immunohistochemical stains show that the tumour cells in specimen II and III are positive for S100 and HMB45 consistent with malignant melanoma.

ADDENDUM SNOMED CODES

Skin - malignant melanoma, metastatic

***** END OF ACCESSION *****

** END OF REPORT COPY **

Source: NCI Genomic Data Commons file ddf0161b-a5a7-4b50-9030-19c6a8977013 (TCGA-EE-A3J5.86A187C5-2FAC-4DEA-9431-020F323E6E5D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).